Somatic mutation profile of tumor specimen b913f361-c5c2-4e49-91ca-719bd8 (aliquot b913f361-c5c2-4e49-91ca-719bd8_D6_1) from CPTAC case 09CO019, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen b913f361-c5c2-4e49-91ca-719bd8: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e27d3bd0-5d1c-4580-b2f8-7a0fd10ad9c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 10c76663-ccb6-4acf-be38-a3264a (Blood Derived Normal), aliquot 10c76663-ccb6-4acf-be38-a3264a_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8b67880-de7f-4f85-990d-242c8b4fad95

The open-access MAF lists 160 somatic variants for this specimen: 103 protein-altering or splice-affecting, 43 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 43, Frame Shift Del 6, Nonsense Mutation 6, Intron 6, Splice Site 3, RNA 3, 3'Flank 2, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4216C>T p.Q1406* | Nonsense Mutation (SNP) | VAF 117/313 reads (37%) | hotspot (GDC flag); catalogued as rs587782518, CM023011, COSV57321535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 111/278 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 94/158 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.2945C>A p.S982* | Nonsense Mutation (SNP) | VAF 133/367 reads (36%) | catalogued as COSV57396050; called by muse, mutect2, varscan2
- ASCC3 | c.982A>C p.I328L | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs376498113; called by muse, mutect2, varscan2
- ATG9A | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 95/176 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.288); catalogued as rs764801042; called by muse, mutect2, varscan2
- CACNA1E | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62402667; called by muse, mutect2, varscan2
- CACNA1F | c.5366G>A p.R1789H | Missense Mutation (SNP) | VAF 134/187 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs201649938; called by muse, mutect2, varscan2
- CCDC74B | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs770194835, COSV100134856; called by muse, mutect2, varscan2
- CUBN | c.6245C>A p.A2082E | Missense Mutation (SNP) | VAF 107/317 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs1417686455; called by muse, mutect2, varscan2
- FES | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758532888; called by muse, mutect2, varscan2
- FPR1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 137/444 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs186613919; called by muse, mutect2, varscan2
- GIMAP6 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 174/475 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs765053253, COSV61033006; called by muse, mutect2, varscan2
- GRIP1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 61/440 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as rs371210390, COSV54048246; called by muse, mutect2, varscan2
- GRM3 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV64466957; called by muse, mutect2, varscan2
- GSTA4 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs774014743, COSV63955120; called by muse, mutect2, varscan2
- HCFC1 | c.3505C>T p.R1169C | Missense Mutation (SNP) | VAF 101/129 reads (78%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs781985655; called by muse, mutect2, varscan2
- HTR6 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201637638, COSV57034689; called by muse, mutect2, varscan2
- INPP5D | c.3295G>A p.G1099R (on ENST00000445964 / NM_001017915.3; = p.G1098R on NM_005541.5) | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.738); catalogued as rs954901187; called by muse, mutect2
- KLHL30 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs867807772; called by muse, mutect2
- LAMA1 | c.5828C>T p.A1943V | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs149983454, COSV67540876; called by muse, mutect2, varscan2
- LILRA2 | c.1444G>A p.G482R (on ENST00000391738 / NM_001130917.3; = p.G465R on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs774107949, COSV52191030, COSV99253905; called by muse, mutect2, varscan2
- MAD1L1 | c.1967C>A p.A656D | Missense Mutation (SNP) | VAF 94/666 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1201226915, COSV99767683; called by muse, varscan2
- MMP17 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 85/441 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as rs1324845064, COSV62178532; called by muse, mutect2, varscan2
- MN1 | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 70/400 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1361403401; called by muse, mutect2, varscan2
- MRPL45 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as rs773667082; called by muse, mutect2, varscan2
- MTSS1 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61497861; called by muse, mutect2, varscan2
- MYH3 | c.3751C>T p.R1251* | Nonsense Mutation (SNP) | VAF 123/418 reads (29%) | catalogued as rs1449708494, COSV56870123; called by muse, mutect2, varscan2
- NTM | c.876C>A p.N292K | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66181610, COSV66196828; called by muse, mutect2, varscan2
- OBSCN | c.19888G>A p.V6630I | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374095284; called by muse, mutect2, varscan2
- OPRPN | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs539624293, COSV68192747; called by muse, mutect2, varscan2
- OR6N1 | c.75T>G p.I25M | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV58649226, COSV58649485; called by mutect2, varscan2
- PADI2 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 137/401 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); catalogued as rs367804119, COSV99070347; called by muse, mutect2, varscan2
- PCDHA9 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 148/928 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs572249977, COSV65324558; called by muse, mutect2, varscan2
- PCDHB6 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as COSV50690449, COSV50693465; called by muse, mutect2, varscan2
- PDE10A | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.154); catalogued as rs756499137, COSV63090599; called by muse, mutect2, varscan2
- PDE10A | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1401781948, COSV63090470; called by muse, mutect2, varscan2
- PKD1 | c.4939A>T p.N1647Y | Missense Mutation (SNP) | VAF 302/786 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51912860; called by muse, varscan2
- PRDM11 | c.749G>A p.R250Q (on ENST00000530656 / NM_001359633.1; = p.R216Q on NM_001256695.1) | Missense Mutation (SNP) | VAF 112/272 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.539); catalogued as rs758925048, COSV55442691; called by muse, varscan2
- PRPSAP1 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs755730825; called by muse, varscan2
- PXDNL | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.105); catalogued as rs752274536, COSV62497910; called by muse, mutect2, varscan2
- RBP3 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 177/483 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781909859; called by muse, mutect2, varscan2
- REPS2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1404723357; called by muse, mutect2, varscan2
- ROS1 | c.3424G>A p.V1142I | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777135627; called by muse, mutect2, varscan2
- RPGRIP1 | c.424C>A p.R142S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV99250572; called by muse, mutect2
- RYR3 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as rs371008189, COSV99066346; called by muse, mutect2, varscan2
- SLC3A1 | c.1626G>T p.K542N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as rs886056071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A3 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 142/257 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.842); catalogued as rs753400209, COSV56097751; called by muse, mutect2, varscan2
- SNX29 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372445217; called by mutect2, varscan2
- SOGA3 | c.2470C>A p.R824S | Missense Mutation (SNP) | VAF 83/436 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs775544839, COSV64106238; called by muse, mutect2, varscan2
- SPDYE5 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.763); catalogued as rs1554482356; called by muse, mutect2
- TGIF2LY | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 126/223 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58291530; called by mutect2, varscan2
- THRB | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 173/441 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM021153, COSV54983024; called by muse, varscan2
- TNRC6C | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs370445459; called by muse, mutect2, varscan2
- VEPH1 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1181522325, COSV62875968; called by muse, mutect2, varscan2
- WDR37 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1272235783; called by muse, mutect2, varscan2
- ZDBF2 | c.5349G>T p.K1783N | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as rs1394935373, COSV65622916; called by muse, mutect2, varscan2
- AHNAK | c.10160T>C p.I3387T | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AKR1C3 | c.681-2del p.X227_splice | Splice Site (DEL) | VAF 58/184 reads (32%) | called by mutect2, pindel, varscan2
- ASB1 | c.326del p.V109Efs*12 | Frame Shift Del (DEL) | VAF 48/326 reads (15%) | called by mutect2, pindel, varscan2
- BCHE | c.1309T>C p.F437L | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.011); called by muse, mutect2
- CDH9 | c.2259G>T p.L753F | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CENPF | c.6920G>A p.R2307K | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLCN6 | c.2188_2189del p.W730Dfs*32 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | called by mutect2, pindel, varscan2
- CNOT11 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2
- CTNNB1 | c.887T>A p.I296N | Missense Mutation (SNP) | VAF 175/521 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- DENND1B | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX16 | c.782A>G p.E261G | Missense Mutation (SNP) | VAF 74/389 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DNAH7 | c.2872C>G p.P958A | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- FOXM1 | c.551_554del p.I184Sfs*6 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- FREM3 | c.5475G>C p.K1825N | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- HIVEP3 | c.5111_5121delinsA p.R1704Kfs*63 | Frame Shift Del (DEL) | VAF 26/170 reads (15%) | called by pindel, varscan2*
- HMCN1 | c.1450T>G p.L484V | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- IL17RE | c.268+1G>T p.X90_splice | Splice Site (SNP) | VAF 47/162 reads (29%) | called by muse, mutect2, varscan2
- LILRB4 | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LIMCH1 | c.2460G>T p.E820D | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAF | c.99A>T p.K33N | Missense Mutation (SNP) | VAF 94/255 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAS1L | c.432dup p.I145Yfs*3 | Frame Shift Ins (INS) | VAF 32/228 reads (14%) | called by mutect2, varscan2
- MUC12 | c.14753C>G p.S4918* (on ENST00000379442; = p.S4775* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 16/432 reads (4%) | called by muse, mutect2
- MUC16 | c.3032C>A p.A1011E | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- NLRP11 | c.2477C>A p.P826H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- NRXN2 | c.2184_2185del p.E729Gfs*18 | Frame Shift Del (DEL) | VAF 120/434 reads (28%) | called by pindel, varscan2
- ONECUT1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- OR11H1 | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 71/433 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- OR2L2 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- OR5F1 | c.353T>A p.M118K | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PJVK | c.550-1G>C p.X184_splice | Splice Site (SNP) | VAF 27/176 reads (15%) | called by muse, mutect2, varscan2
- PRKACG | c.773T>G p.F258C | Missense Mutation (SNP) | VAF 196/577 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- PSEN2 | c.1259T>G p.I420S | Missense Mutation (SNP) | VAF 22/588 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RASSF7 | c.574C>A p.R192S | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- RGPD2 | c.4079A>G p.D1360G | Missense Mutation (SNP) | VAF 20/681 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RXFP2 | c.1259T>A p.I420K | Missense Mutation (SNP) | VAF 260/397 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SLC16A3 | c.433C>A p.R145S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SLC16A5 | c.650C>A p.A217D | Missense Mutation (SNP) | VAF 102/600 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- SLC7A6OS | c.910del p.H304Tfs*35 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- SLIT2 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.068); called by muse, varscan2
- SYNGR3 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 109/259 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THAP12 | c.1459A>T p.K487* | Nonsense Mutation (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- TLR7 | c.2986C>A p.Q996K | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.077); called by muse, mutect2
- TMEM239 | c.349G>A p.A117T (on ENST00000361033 / NM_001318207.1; = p.A74T on NM_001167670.3) | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); called by muse, mutect2
- ZEB2 | c.2558C>A p.S853Y | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ZNF536 | c.2771G>T p.S924I | Missense Mutation (SNP) | VAF 143/443 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ZNF652 | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ADGRL3 | c.4545G>A p.P1515= (on ENST00000506720 / NM_001322402.2; = p.P1404= on NM_015236.6) | Silent (SNP) | VAF 120/343 reads (35%) | catalogued as rs763827190, COSV101541213; called by muse, mutect2, varscan2
- AGO2 | c.621G>T p.R207= | Silent (SNP) | VAF 63/147 reads (43%) | catalogued as COSV55046423; called by muse, mutect2, varscan2
- AMPH | c.237G>A p.E79= | Silent (SNP) | VAF 47/190 reads (25%) | catalogued as rs143836466; called by muse, mutect2, varscan2
- ASPM | c.10173T>C p.S3391= | Silent (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- AVPR1A | c.915G>A p.A305= | Silent (SNP) | VAF 66/385 reads (17%) | catalogued as rs746375987, COSV100146854; called by muse, mutect2, varscan2
- BPIFB3 | c.81G>A p.T27= | Silent (SNP) | VAF 190/306 reads (62%) | catalogued as rs149497264; called by muse, mutect2, varscan2
- CADM3 | c.1113C>T p.D371= (on ENST00000368125 / NM_001127173.3; = p.D405= on NM_021189.5) | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs772803114; called by muse, mutect2, varscan2
- CARD10 | c.2568G>T p.A856= | Silent (SNP) | VAF 34/196 reads (17%) | catalogued as rs762865611; called by muse, mutect2, varscan2
- CELSR2 | c.3504C>T p.N1168= | Silent (SNP) | VAF 64/186 reads (34%) | catalogued as COSV54769028; called by muse, mutect2, varscan2
- CNOT6 | c.18C>T p.Y6= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99993824; called by muse, mutect2, varscan2
- COL11A1 | c.1440A>C p.P480= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs758274596; called by muse, mutect2, varscan2
- DCAF12L1 | c.639C>T p.R213= | Silent (SNP) | VAF 328/420 reads (78%) | catalogued as rs375986905, COSV64421386; called by muse, mutect2, varscan2
- EHD2 | c.996C>T p.I332= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV54410872; called by muse, mutect2, varscan2
- EXO1 | c.1011G>A p.Q337= | Silent (SNP) | VAF 29/225 reads (13%) | catalogued as rs368445876; called by muse, mutect2, varscan2
- EZH2 | c.73C>A p.R25= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV57446240, COSV57461859; called by muse, mutect2
- FAT1 | c.6111G>A p.T2037= | Silent (SNP) | VAF 72/172 reads (42%) | catalogued as rs533960249, COSV71673122; ClinVar: likely benign; called by muse, mutect2, varscan2
- GOLGA8K | c.393A>G p.L131= | Silent (SNP) | VAF 65/255 reads (25%) | called by muse, mutect2, varscan2
- IBSP | c.156T>C p.Y52= | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- ITPR3 | c.6003G>A p.L2001= | Silent (SNP) | VAF 18/338 reads (5%) | catalogued as rs1425304024; called by muse, mutect2
- MC3R | c.429C>T p.Y143= | Silent (SNP) | VAF 113/698 reads (16%) | catalogued as rs148382606; called by muse, mutect2, varscan2
- NPM2 | c.522C>T p.S174= | Silent (SNP) | VAF 45/159 reads (28%) | catalogued as rs761060148; called by muse, mutect2, varscan2
- OR5B3 | c.303C>A p.I101= | Silent (SNP) | VAF 103/345 reads (30%) | catalogued as COSV58678770; called by muse, mutect2, varscan2
- PCDHGB3 | c.528G>A p.P176= | Silent (SNP) | VAF 46/245 reads (19%) | catalogued as rs563952977, COSV54034350; called by muse, mutect2, varscan2
- PCDHGB7 | c.2016G>T p.L672= | Silent (SNP) | VAF 114/325 reads (35%) | called by muse, mutect2, varscan2
- PLA2R1 | c.4377G>A p.E1459= | Silent (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- PRICKLE1 | c.1053C>T p.L351= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as COSV61542744; called by muse, mutect2, varscan2
- PRKCZ | c.498G>T p.L166= | Silent (SNP) | VAF 32/235 reads (14%) | called by muse, mutect2, varscan2
- PTPN14 | c.420G>T p.R140= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV65284254; called by muse, mutect2, varscan2
- RAB10 | c.381C>T p.D127= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs750860761; called by mutect2, varscan2
- RAB11B | c.177C>T p.T59= | Silent (SNP) | VAF 63/322 reads (20%) | catalogued as rs1398356902; called by muse, mutect2, varscan2
- RB1 | c.48C>T p.A16= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- RBMS3 | c.918G>A p.P306= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs763922967, COSV56154480; called by muse, mutect2, varscan2
- RXFP2 | c.1260A>T p.I420= | Silent (SNP) | VAF 257/395 reads (65%) | called by muse, mutect2, varscan2
- SLC24A3 | c.528C>T p.G176= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as rs115896900, COSV60118991; called by muse, mutect2, varscan2
- TAS2R10 | c.90A>G p.V30= | Silent (SNP) | VAF 69/165 reads (42%) | catalogued as rs1001773125; called by muse, mutect2, varscan2
- THRB | c.948C>T p.R316= | Silent (SNP) | VAF 103/312 reads (33%) | catalogued as rs759003084, COSV54979135; called by muse, mutect2, varscan2
- THSD7B | c.357C>T p.Y119= | Silent (SNP) | VAF 194/350 reads (55%) | catalogued as rs1455127441, COSV55663354; called by muse, mutect2, varscan2
- TIMP2 | c.618C>T p.G206= | Silent (SNP) | VAF 57/401 reads (14%) | catalogued as rs377028476; called by muse, mutect2, varscan2
- TMPRSS11D | c.942A>G p.Q314= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs202115417, COSV52227073; called by muse, mutect2, varscan2
- UNC5B | c.1140C>T p.L380= | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as rs750780663; called by muse, mutect2, varscan2
- VWC2L | c.609G>A p.G203= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs1383251718; called by muse, mutect2, varscan2
- WDR49 | c.1429C>A p.R477= (on ENST00000308378 / NM_001366158.1; = p.R818= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 72/176 reads (41%) | called by muse, mutect2, varscan2
- WDR87 | c.1377A>G p.E459= | Silent (SNP) | VAF 71/213 reads (33%) | catalogued as COSV58194609; called by muse, mutect2, varscan2
- ACTN2 | c.-32C>T | 5'UTR (SNP) | VAF 18/30 reads (60%) | catalogued as COSV63974083; called by muse, varscan2
- AMFR | c.*411C>T | 3'UTR (SNP) | VAF 76/254 reads (30%) | catalogued as rs372252237; called by muse, mutect2, varscan2
- ART5 | c.821-66T>C | Intron (SNP) | VAF 93/280 reads (33%) | called by muse, mutect2, varscan2
- CCDC83 | chr11:85853256 T>C | 5'Flank (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93733501 T>C | 3'Flank (SNP) | VAF 67/171 reads (39%) | called by muse, mutect2, varscan2
- CICP4 | chr20:64287771 C>G | 3'Flank (SNP) | VAF 32/347 reads (9%) | catalogued as rs1185179205; called by muse, mutect2
- DGKI | c.2147+6434G>T | Intron (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- GGNBP1 | n.882T>C | RNA (SNP) | VAF 24/174 reads (14%) | catalogued as rs1251855411; called by muse, mutect2, varscan2
- KAT6B | c.928+25del | Intron (DEL) | VAF 36/208 reads (17%) | called by mutect2, pindel, varscan2
- LARGE1 | c.616-7173dup | Intron (INS) | VAF 7/53 reads (13%) | catalogued as rs1313773187; called by mutect2, pindel, varscan2
- PARGP1 | n.276_287del | RNA (DEL) | VAF 100/330 reads (30%) | called by mutect2, varscan2
- STAU2 | c.1531-16298C>T | Intron (SNP) | VAF 37/130 reads (28%) | catalogued as rs767965465; called by muse, mutect2, varscan2
- TAC1 | c.221-19A>T | Intron (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2, varscan2
- TRIM51BP | n.1085G>A | RNA (SNP) | VAF 90/582 reads (15%) | catalogued as rs757234994; called by mutect2, varscan2
